FM case AD5334 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/f0714380-a0e5-4967-932b-3b394cd9625c

Male, 64.2 years: Melanoma, NOS (ICD-O-3 8720/3) of the anus; primary biopsied or resected from the anal canal. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
